Somatic mutation profile of tumor specimen C3N-03183-02 (aliquot CPT0206670007) from CPTAC case C3N-03183, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.7 years (19,616 days).
Specimen C3N-03183-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25f0207f-aaab-4f60-be77-50ad66cdf296.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03183-71 (Blood Derived Normal), aliquot CPT0206720002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca158add-fe07-4ea9-ab05-469d6b59d1a9

The open-access MAF lists 52 somatic variants for this specimen: 29 protein-altering or splice-affecting, 18 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 18, Intron 4, Splice Site 3, Frame Shift Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 958/1313 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1477025000, COSV51779162, COSV51807036; called by muse, mutect2, varscan2
- PTEN | c.755A>G p.D252G | Missense Mutation (SNP) | VAF 88/141 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs121909239, CM051216, CM159947, COSV64289881, COSV64296805, COSV64297163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATMIN | c.2365A>G p.M789V | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs761128611, COSV55145712; called by muse, mutect2, varscan2
- CCBE1 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 135/385 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199902030; called by muse, mutect2, varscan2
- CERT1 | c.13T>G p.C5G | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs909601589; called by muse, mutect2, varscan2
- DCX | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 128/179 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as CM036066; called by muse, mutect2, varscan2
- IGHV3-49 | c.125C>A p.T42K | Missense Mutation (SNP) | VAF 90/271 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs782549145; called by muse, mutect2
- KLK4 | c.612+1G>A p.X204_splice | Splice Site (SNP) | VAF 120/340 reads (35%) | catalogued as COSV100133701; called by muse, mutect2, varscan2
- KRT17 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 188/502 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as rs200744890; called by muse, mutect2, varscan2
- MGAT4C | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs566418071, COSV59832100, COSV59837748; called by muse, varscan2
- OTOP1 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 88/344 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.877); catalogued as COSV56393047; called by muse, mutect2, varscan2
- POTEJ | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 122/428 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs776474594; called by muse, mutect2, varscan2
- RGL3 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs779419722, COSV66506061; called by muse, mutect2
- TNS3 | c.3937G>A p.V1313M | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60788679; called by muse, mutect2
- ZNF729 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs536246557; called by muse, mutect2, varscan2
- A2ML1 | c.334A>C p.K112Q | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- BCL11A | c.976del p.L326Sfs*61 (on ENST00000335712 / NM_001365609.1; = p.L360Sfs*61 on NM_018014.4) | Frame Shift Del (DEL) | VAF 58/158 reads (37%) | called by mutect2, pindel
- HSD17B12 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, varscan2
- JPH4 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- LCORL | c.1239A>C p.K413N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MUC12 | c.6422G>A p.G2141D (on ENST00000379442; = p.G1998D on NM_001164462.1) | Missense Mutation (SNP) | VAF 106/2763 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- NCAPG | c.1828T>C p.C610R | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OR2W1 | c.869A>T p.Y290F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RAB3IP | c.732+1G>A p.X244_splice (on ENST00000550536 / NM_175623.4; = p.X228_splice on NM_022456.5) | Splice Site (SNP) | VAF 41/111 reads (37%) | called by muse, mutect2, varscan2
- RGS22 | c.1499del p.P500Lfs*25 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | called by mutect2, pindel, varscan2
- SLC4A3 | c.2980C>T p.L994F | Missense Mutation (SNP) | VAF 209/538 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- TBC1D19 | c.1345G>C p.V449L | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- VIRMA | c.4383+1G>C p.X1461_splice | Splice Site (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- ZFR | c.1426T>C p.S476P | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACMSD | c.459C>T p.N153= | Silent (SNP) | VAF 140/317 reads (44%) | catalogued as rs749496752; called by muse, mutect2, varscan2
- ADD2 | c.1398C>T p.D466= | Silent (SNP) | VAF 39/143 reads (27%) | catalogued as rs188058882; called by muse, mutect2, varscan2
- ALX4 | c.900C>T p.Y300= | Silent (SNP) | VAF 101/221 reads (46%) | catalogued as rs373589363; called by muse, mutect2, varscan2
- CLEC4M | c.261C>T p.D87= | Silent (SNP) | VAF 110/281 reads (39%) | catalogued as rs144919911; called by muse, mutect2, varscan2
- CNTN6 | c.2911T>C p.L971= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV100610987; called by muse, mutect2, varscan2
- CYP2D6 | c.366G>A p.A122= | Silent (SNP) | VAF 96/299 reads (32%) | catalogued as rs756389811; called by muse, mutect2, varscan2
- DZIP1 | c.2223C>T p.V741= (on ENST00000347108; = p.V722= on NM_014934.5) | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as rs1213729193, COSV100713982; called by muse, mutect2, varscan2
- HCN1 | c.2229G>A p.P743= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as COSV57510678; called by muse, mutect2, varscan2
- LAMA1 | c.2331C>T p.Y777= | Silent (SNP) | VAF 220/566 reads (39%) | catalogued as rs185274541, COSV67542326; called by muse, mutect2, varscan2
- LARP4 | c.951C>T p.Y317= | Silent (SNP) | VAF 53/187 reads (28%) | called by muse, mutect2, varscan2
- MGA | c.4560G>A p.A1520= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as rs186253530, COSV99582052; called by muse, mutect2, varscan2
- MUC16 | c.36651C>T p.S12217= | Silent (SNP) | VAF 76/173 reads (44%) | called by muse, mutect2, varscan2
- NEU2 | c.972G>A p.P324= | Silent (SNP) | VAF 65/185 reads (35%) | catalogued as rs906823914, COSV52091862; called by muse, mutect2, varscan2
- NLRP11 | c.1680G>A p.T560= | Silent (SNP) | VAF 47/138 reads (34%) | catalogued as rs369119219, COSV64088102; called by muse, mutect2, varscan2
- SCN1A | c.1278C>T p.Y426= | Silent (SNP) | VAF 160/393 reads (41%) | catalogued as rs146515561; called by muse, mutect2, varscan2
- SLAMF7 | c.819C>T p.N273= | Silent (SNP) | VAF 60/189 reads (32%) | called by muse, mutect2, varscan2
- SLC44A2 | c.1377C>T p.F459= | Silent (SNP) | VAF 114/285 reads (40%) | catalogued as COSV59834966; called by muse, mutect2, varscan2
- TENM3 | c.7716G>A p.E2572= | Silent (SNP) | VAF 150/425 reads (35%) | catalogued as COSV101305259; called by muse, mutect2, varscan2
- AC109583.1 | c.-1319+932C>T | Intron (SNP) | VAF 104/306 reads (34%) | catalogued as rs1219827580; called by mutect2, varscan2
- ACSF3 | c.*398G>A | 3'UTR (SNP) | VAF 128/401 reads (32%) | catalogued as rs919210983; called by muse, mutect2, varscan2
- AMPH | c.1272+1438C>T | Intron (SNP) | VAF 39/204 reads (19%) | catalogued as rs780335614; called by muse, mutect2, varscan2
- C1orf159 | c.553+595_553+611del | Intron (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel
- FAM3B | c.397+155C>T | Intron (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
